Gene-level copy-number profile of tumor specimen TARGET-10-PANRYM-09A from TARGET case TARGET-10-PANRYM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (852 days).
Specimen TARGET-10-PANRYM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.07c58eb5-d55b-590d-abc0-78c3f86aded1.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PANRYM-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 355 have no estimate.
https://portal.gdc.cancer.gov/files/971422ce-887f-408f-ab66-1e9bde648159

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 525; copy number 1: 28; copy number 2: 40,085; copy number 3: 18,843; copy number 4: 741; copy number 5: 46.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr15:76,586,647–76,586,691, 1 gene: MIR3713.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:46,233,885–47,730,436, 46 genes, copy number 5: ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R, GPRIN2, SYT15, AL356056.2, AL356056.1, SHLD2P1, LINC02637, RHEBP1, RN7SL248P, FAM245B, CTSLP3, GLUD1P2, AL731733.1, BMS1P1, RNA5SP311, AGAP13P, FRMPD2B, PTPN20, GDF10, GDF2, RBP3, ZNF488, ANXA8, AL591684.3, FAM25G, AL591684.1, AGAP9, AL591684.2, RNA5SP312, BMS1P2, BX547991.1, DUSP8P1, CTSLP2, LINC02675, SHLD2P3, RN7SL453P, RHEBP2.

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
